Somatic mutation profile of tumor specimen TCGA-HC-7747-01A (aliquot TCGA-HC-7747-01A-11D-2114-08) from TCGA case TCGA-HC-7747, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 52.5 years (19,188 days).
Specimen TCGA-HC-7747-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 654d2a34-1bdf-464d-89b4-36c47845194f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7747-10A (Blood Derived Normal), aliquot TCGA-HC-7747-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5cff541-26ab-4982-bf25-cdf7734f7745

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 15, Silent 8, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 11/258 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57246789; called by muse, mutect2
- ACAN | c.2804G>A p.G935D | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.966); catalogued as COSV61360861; called by muse, mutect2
- CCDC180 | c.4333C>T p.R1445W | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs141047389; called by mutect2, varscan2
- CDKL2 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1007638893, COSV56733525; called by muse, mutect2, varscan2
- CFAP161 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 5/73 reads (7%) | catalogued as COSV54429333; called by muse, mutect2
- CSTF2T | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.05); catalogued as COSV58656496; called by muse, mutect2
- DEGS2 | c.833A>C p.K278T | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV59784409; called by muse, mutect2
- DNPEP | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV56110858; called by muse, mutect2, varscan2
- FAM199X | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.018); catalogued as rs938706251, COSV55433610; called by muse, mutect2
- GAD2 | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 7/174 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV52157846; called by muse, mutect2
- GINS3 | c.403T>C p.S135P | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV58919818; called by muse, mutect2, varscan2
- MAK | c.1439A>G p.Y480C | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57565447; called by muse, mutect2
- MRPS23 | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV58032289; called by muse, mutect2
- NHS | c.2497C>T p.R833C | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66275187; called by muse, mutect2
- PPP2R2B | c.368G>A p.R123H (on ENST00000394409; = p.R189H on NM_181674.2) | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs374783257; called by muse, mutect2
- RP1 | c.3973G>A p.G1325R | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1322767371, COSV55117189; called by muse, mutect2, varscan2
- ATP2A2 | c.1533dup p.F512Vfs*7 | Frame Shift Ins (INS) | VAF 15/75 reads (20%) | called by mutect2, pindel, varscan2
- CACHD1 | c.2988C>T p.C996= | Silent (SNP) | VAF 29/254 reads (11%) | catalogued as rs150699745; called by muse, mutect2, varscan2
- CATSPERG | c.2898C>T p.D966= | Silent (SNP) | VAF 34/511 reads (7%) | catalogued as rs2302184; called by muse, mutect2
- CKMT2 | c.210C>T p.P70= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as rs778061756, COSV54173430; called by muse, mutect2, varscan2
- DQX1 | c.1122G>A p.L374= | Silent (SNP) | VAF 9/259 reads (3%) | catalogued as COSV66353230; called by muse, mutect2
- LRP2 | c.1414C>T p.L472= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as rs968969535, COSV55542392; called by muse, mutect2, varscan2
- MOXD1 | c.954A>C p.I318= | Silent (SNP) | VAF 6/89 reads (7%) | catalogued as COSV60943565, COSV60944618; called by muse, mutect2
- SCN10A | c.4584C>T p.F1528= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as rs141828577; ClinVar: likely benign; called by muse, mutect2, varscan2
- TCF3 | c.1629G>A p.K543= | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as rs1052738, COSV53648729; called by muse, mutect2, varscan2
